Gene-level copy-number profile of tumor specimen TCGA-12-1092-01B from TCGA case TCGA-12-1092, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.6 years (21,411 days).
Specimen TCGA-12-1092-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.221e1e30-d221-4c56-8816-737c1572607a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1092-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba2d4721-55c6-49ae-9ee7-e703d1d0ce28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 8,004; copy number 2: 43,117; copy number 3: 8,646; copy number 18: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-1092-01B-01D-0517-01): tumor purity 0.66, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:33,597,057–33,600,989, 1 gene: AL161851.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–205,078,289, 45 genes, copy number 18 (within-gene range 2–18): ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2.

Autosomal genes at a single copy (total copy number 1): 5,627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
